Gene-level copy-number profile of tumor specimen TCGA-G7-7502-01A from TCGA case TCGA-G7-7502, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 83.1 years (30,346 days).
Specimen TCGA-G7-7502-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRP.a45bedd1-bc9b-4696-8730-4af86ccbb812.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G7-7502-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 350 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cc65596f-fbec-4b01-bf43-60893f8b8eaf

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 2,364; copy number 2: 25,630; copy number 3: 27,203; copy number 4: 5,056.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G7-7502-01A-11D-2200-01): tumor purity 0.56, ploidy 2.83, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene (within-gene range 0–2): RSRP1.
- chr1:25,266,102–25,330,445, 3 genes: AL031432.2, RHD, SDHDP6.
- chr1:152,600,662–152,601,086, 1 gene: LCE3C.
- chr1:152,786,214–152,788,426, 1 gene: LCE1E.
- chr15:34,358,633–34,597,558, 14 genes (within-gene range 0–2): LPCAT4, ACTG1P15, GOLGA8A, MIR1233-1, AC025678.1, AC025678.2, AC025678.3, HNRNPLP2, FSCN1P1, DNM1P5, GOLGA8B, MIR1233-2, AC027139.1, AC100834.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
